Somatic mutation profile of tumor specimen TARGET-10-PARSKV-09A (aliquot TARGET-10-PARSKV-09A-01D) from TARGET case TARGET-10-PARSKV, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.0 years (2,563 days).
Specimen TARGET-10-PARSKV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8e4aeda8-8eba-4b1e-b2e1-6f1f158def0f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARSKV-10A (Blood Derived Normal), aliquot TARGET-10-PARSKV-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/99f91bfd-a6ef-412d-b309-5a5645f6b2a5

The open-access MAF lists 16 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, Intron 3, RNA 1, Frame Shift Ins 1, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRLF2 | c.695T>G p.F232C | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs1057519743, COSV67493408; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DST | c.15634G>A p.E5212K (on ENST00000361203 / NM_001374722.1; = p.E2800K on NM_015548.5) | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.406); catalogued as rs770951734, COSV99756021; called by muse, mutect2, varscan2
- FAT1 | c.12885C>A p.H4295Q | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.939); catalogued as rs1022833791; called by muse, mutect2, varscan2
- HSPA12A | c.851G>A p.R284Q | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.571); catalogued as rs539181870; called by muse, mutect2
- PAX5 | c.416T>C p.I139T | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as COSV63907360; called by muse, varscan2
- RYR2 | c.3907C>T p.R1303C | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as rs774403167, COSV63667858; called by muse, mutect2, varscan2
- NSMCE1 | c.714_715dup p.I239Rfs*17 | Frame Shift Ins (INS) | VAF 17/53 reads (32%) | called by mutect2, pindel, varscan2
- BCHE | c.987C>T p.D329= | Silent (SNP) | VAF 46/112 reads (41%) | catalogued as rs766000843; called by muse, mutect2, varscan2
- DHX32 | c.2196G>A p.T732= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs757734941, COSV52943084; called by muse, mutect2, varscan2
- GAREM1 | c.357C>T p.R119= | Silent (SNP) | VAF 41/99 reads (41%) | catalogued as rs775839313, COSV52507354; called by muse, mutect2, varscan2
- AC007546.3 | n.159_170delinsGGGAA | RNA (DEL) | VAF 14/45 reads (31%) | called by pindel, varscan2*
- AC107023.1 | n.25+3197G>A | Intron (SNP) | VAF 38/89 reads (43%) | catalogued as rs766062557; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73820873 A>G | 3'Flank (SNP) | VAF 32/37 reads (86%) | called by muse, mutect2, varscan2
- CEACAM8 | c.*22A>G | 3'UTR (SNP) | VAF 43/95 reads (45%) | called by muse, mutect2, varscan2
- PPIA | c.189+81A>G | Intron (SNP) | VAF 40/90 reads (44%) | called by muse, mutect2, varscan2
- PRKACA | c.46+3310C>G | Intron (SNP) | VAF 23/59 reads (39%) | called by muse, mutect2, varscan2
